Somatic mutation profile of tumor specimen C3L-06716-01 (aliquot CPT0393460006) from CPTAC case C3L-06716, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G4; Age at diagnosis: 69.1 years (25,221 days).
Specimen C3L-06716-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bcf75df6-89ba-4c2a-a727-eed8577dd057.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06716-31 (Blood Derived Normal), aliquot CPT0390780005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5501eaad-c2e6-49f1-980c-18905c9e7986

The open-access MAF lists 243 somatic variants for this specimen: 161 protein-altering or splice-affecting, 71 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 147, Silent 71, Nonsense Mutation 5, Frame Shift Ins 4, 3'UTR 3, Frame Shift Del 3, Intron 3, 5'UTR 2, RNA 2, 5'Flank 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 36/237 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 35/266 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.124); catalogued as rs750817645; called by muse, mutect2, varscan2
- AC093525.2 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 40/398 reads (10%) | PolyPhen benign (0); catalogued as rs369475799; called by muse, mutect2
- ALOX15B | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 30/255 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as rs375708086, COSV66479103; called by muse, mutect2
- AMIGO3 | c.1274C>T p.P425L | Missense Mutation (SNP) | VAF 13/495 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.518); catalogued as rs1407143107, COSV100246799, COSV57540089; called by muse, mutect2
- AMPD3 | c.1138C>T p.R380W (on ENST00000396553 / NM_001025389.2; = p.R389W on NM_000480.3) | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777939609; called by muse, mutect2, varscan2
- AP4E1 | c.1600A>G p.I534V | Missense Mutation (SNP) | VAF 24/348 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.047); catalogued as rs1343407484; called by muse, mutect2
- BRINP1 | c.1531C>T p.R511C | Missense Mutation (SNP) | VAF 33/409 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56298786; called by muse, mutect2
- C13orf42 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 28/348 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs1027350710; called by muse, mutect2
- C16orf86 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 41/400 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.037); catalogued as rs1490895884, COSV54675712; called by muse, mutect2
- CACNA1S | c.3853G>A p.G1285S | Missense Mutation (SNP) | VAF 43/368 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768535906, COSV62940596, COSV62941559; called by muse, mutect2, varscan2
- CAMK2G | c.637C>G p.P213A | Missense Mutation (SNP) | VAF 39/335 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV59483900; called by muse, mutect2, varscan2
- CBL | c.1919C>T p.T640M | Missense Mutation (SNP) | VAF 36/255 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.127); catalogued as rs1263873227; called by muse, mutect2, varscan2
- CHMP1B | c.494A>T p.N165I | Missense Mutation (SNP) | VAF 40/389 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs774638280; called by muse, mutect2, varscan2
- CHPF | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 48/507 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.601); catalogued as rs753681580, COSV99704548; called by muse, mutect2
- CPXCR1 | c.50A>G p.K17R | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as COSV99342147, COSV99342500; called by muse, mutect2, varscan2
- CSMD1 | c.4318T>G p.F1440V (on ENST00000520002; = p.F1439V on NM_033225.6) | Missense Mutation (SNP) | VAF 32/346 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100142201, COSV59314221; called by muse, mutect2
- CSMD1 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 26/409 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as rs374354109; called by muse, mutect2
- CSMD3 | c.160A>G p.T54A | Missense Mutation (SNP) | VAF 20/324 reads (6%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.006); catalogued as COSV52171768; called by muse, mutect2
- CTNND2 | c.2704C>T p.R902* | Nonsense Mutation (SNP) | VAF 36/434 reads (8%) | catalogued as rs769715162, COSV58888672; called by muse, mutect2
- CYP11B2 | c.1256G>A p.R419K | Missense Mutation (SNP) | VAF 46/564 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV59995541, COSV59997093; called by muse, mutect2
- DACT2 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 46/368 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.169); catalogued as rs1202036460; called by muse, mutect2, varscan2
- DCC | c.1634T>C p.L545P | Missense Mutation (SNP) | VAF 41/360 reads (11%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.53); catalogued as COSV59086205; called by muse, mutect2, varscan2
- DPAGT1 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 26/257 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs771322037, COSV53828529, COSV53830489; called by muse, mutect2, varscan2
- DSCAML1 | c.4850C>T p.A1617V (on ENST00000321322; = p.A1557V on NM_020693.4) | Missense Mutation (SNP) | VAF 43/408 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58398476; called by muse, mutect2, varscan2
- DSEL | c.2098T>C p.S700P | Missense Mutation (SNP) | VAF 39/360 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs770748346; called by muse, mutect2, varscan2
- DVL2 | c.1894C>T p.R632W | Missense Mutation (SNP) | VAF 46/582 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs200445258, COSV50038910; called by muse, mutect2
- EBF1 | c.1522G>A p.G508S | Missense Mutation (SNP) | VAF 37/352 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.048); catalogued as rs760492043; called by muse, mutect2, varscan2
- ELOA2 | c.1853G>A p.R618Q | Missense Mutation (SNP) | VAF 43/359 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as COSV55295883; called by muse, mutect2, varscan2
- EPHA8 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 53/423 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1333861109, COSV99385800; called by muse, mutect2, varscan2
- EYS | c.1635A>C p.E545D | Missense Mutation (SNP) | VAF 17/277 reads (6%) | SIFT tolerated (0.78); PolyPhen benign (0.017); catalogued as COSV60991316; called by muse, mutect2
- FAM71E1 | c.107A>G p.H36R | Missense Mutation (SNP) | VAF 58/490 reads (12%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); catalogued as rs769400910; called by muse, mutect2, varscan2
- FKRP | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 70/611 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.098); catalogued as rs1449983261; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLNC | c.3241G>A p.A1081T | Missense Mutation (SNP) | VAF 49/502 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); catalogued as rs781760817; ClinVar: uncertain significance; called by muse, mutect2
- FLYWCH1 | c.442C>T p.R148C (on ENST00000253928 / NM_001308068.2; = p.R147C on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/471 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs201482326; called by muse, mutect2, varscan2
- GARNL3 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 42/233 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1332708016, COSV59226978; called by muse, mutect2, varscan2
- GDF7 | c.1124C>A p.A375E | Missense Mutation (SNP) | VAF 38/465 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55348278; called by muse, mutect2
- GRM8 | c.2453T>G p.L818R | Missense Mutation (SNP) | VAF 18/217 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV58829629, COSV58836480; called by muse, mutect2
- HDAC5 | c.383A>G p.Q128R | Missense Mutation (SNP) | VAF 36/419 reads (9%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.973); catalogued as rs138900388, COSV99870988; called by muse, mutect2, varscan2
- HHIPL1 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 51/453 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.135); catalogued as rs369853485, COSV58092352; called by muse, mutect2, varscan2
- INSRR | c.3763C>T p.R1255C | Missense Mutation (SNP) | VAF 48/383 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as rs747977097, COSV63870842; called by muse, mutect2, varscan2
- INSYN2B | c.1169T>G p.L390R | Missense Mutation (SNP) | VAF 42/343 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV56989492; called by muse, mutect2, varscan2
- IQCG | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 41/427 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as rs1185081980; called by muse, mutect2
- IRX3 | c.781G>A p.G261S | Missense Mutation (SNP) | VAF 53/521 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs368665720; called by muse, mutect2, varscan2
- KCND2 | c.1015G>A p.A339T | Missense Mutation (SNP) | VAF 38/276 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); catalogued as COSV58575148; called by muse, mutect2, varscan2
- KLK6 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 39/330 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777841287, COSV100037817, COSV59565159; called by muse, mutect2, varscan2
- LAT | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 48/371 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs921362084; called by muse, mutect2, varscan2
- LRP1B | c.9191G>A p.R3064Q | Missense Mutation (SNP) | VAF 13/223 reads (6%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.834); catalogued as rs1196321476, COSV67206893; called by muse, mutect2
- METRNL | c.179C>T p.T60M | Missense Mutation (SNP) | VAF 40/375 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs370020717; called by muse, mutect2, varscan2
- MMP11 | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 34/330 reads (10%) | catalogued as rs566121317, COSV53156860; called by muse, mutect2, varscan2
- MYBPC2 | c.2504C>T p.A835V | Missense Mutation (SNP) | VAF 28/247 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748773939, COSV100731738; called by muse, mutect2, varscan2
- NCOR1 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV51980189; called by muse, mutect2
- NLRP3 | c.833G>T p.C278F | Missense Mutation (SNP) | VAF 16/350 reads (5%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.786); catalogued as COSV60232478; called by muse, mutect2
- OLIG3 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 52/463 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV62988235; called by muse, mutect2, varscan2
- OR4A15 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 40/454 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs374555766, COSV59036488; called by muse, mutect2
- OR8H1 | c.656C>A p.S219Y | Missense Mutation (SNP) | VAF 42/374 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV57295404; called by muse, mutect2, varscan2
- PASD1 | c.1752G>T p.Q584H | Missense Mutation (SNP) | VAF 72/272 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100949017, COSV64856831; called by muse, mutect2, varscan2
- PCDHA12 | c.449C>A p.S150Y | Missense Mutation (SNP) | VAF 26/430 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.363); catalogued as COSV56475916; called by muse, mutect2
- PCDHA8 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 72/680 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.057); catalogued as COSV65335056; called by muse, mutect2, varscan2
- PCDHB15 | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 82/701 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.327); catalogued as COSV50859515; called by muse, mutect2, varscan2
- PCSK5 | c.3667G>A p.V1223I | Missense Mutation (SNP) | VAF 43/366 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs764311048; called by muse, mutect2, varscan2
- PDZRN4 | c.662A>C p.K221T | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.18); catalogued as COSV68417996; called by muse, mutect2
- PKD1L1 | c.1783C>T p.R595W | Missense Mutation (SNP) | VAF 67/324 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754076706, COSV56973388; called by muse, varscan2
- PLA2G4E | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as rs763377151, COSV68150004; called by muse, mutect2, varscan2
- PLEC | c.7507C>T p.R2503W (on ENST00000322810 / NM_201380.4; = p.R2393W on NM_000445.5) | Missense Mutation (SNP) | VAF 85/508 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.727); catalogued as rs782676972; called by muse, mutect2, varscan2
- PLPPR3 | c.1643C>T p.A548V (on ENST00000520876 / NM_001270366.2; = p.A576V on NM_024888.2) | Missense Mutation (SNP) | VAF 61/429 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1468733503; called by muse, mutect2, varscan2
- POM121L12 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 54/630 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs755281512, COSV101374925, COSV68693180; called by muse, mutect2
- PPP1R3A | c.3069A>C p.E1023D | Missense Mutation (SNP) | VAF 34/427 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.318); catalogued as COSV52893421; called by muse, mutect2
- PTN | c.288C>T p.G96= | Splice Region (SNP) | VAF 22/242 reads (9%) | catalogued as rs779082764, COSV61965206; called by muse, mutect2
- PTPN3 | c.1934C>T p.T645M | Missense Mutation (SNP) | VAF 36/264 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs1361970381, COSV52705303; called by muse, mutect2, varscan2
- PTPRN2 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 34/318 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs372551467; called by mutect2, varscan2
- RAP1B | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 26/312 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); catalogued as rs1359697089, COSV51668437; called by muse, mutect2
- RBMXL3 | c.2428G>A p.D810N | Missense Mutation (SNP) | VAF 75/306 reads (25%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as rs1273797983, COSV57754029; called by muse, mutect2, varscan2
- RYR2 | c.3908G>A p.R1303H | Missense Mutation (SNP) | VAF 36/320 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as rs766670579, COSV63663015; ClinVar: uncertain significance; called by muse, varscan2
- SLC22A12 | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 40/384 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.146); catalogued as rs761277987, COSV60571774; called by muse, mutect2, varscan2
- SLC6A9 | c.677C>T p.T226M (on ENST00000360584 / NM_201649.4; = p.T172M on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/512 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1007434363, COSV62210763; called by muse, mutect2
- SLITRK3 | c.1232A>T p.K411M | Missense Mutation (SNP) | VAF 45/386 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99579488; called by muse, mutect2, varscan2
- SMARCA4 | c.3575G>T p.R1192L | Missense Mutation (SNP) | VAF 37/288 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60785906, COSV60794673; called by muse, mutect2, varscan2
- STAT3 | c.1711C>T p.L571F | Missense Mutation (SNP) | VAF 43/335 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV52890888; called by muse, mutect2, varscan2
- SULF1 | c.1689A>C p.E563D | Missense Mutation (SNP) | VAF 42/488 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.028); catalogued as COSV52673317; called by muse, mutect2
- SV2A | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 45/538 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs587760193, COSV64966057; called by muse, mutect2
- SYT14 | c.1109A>C p.N370T | Missense Mutation (SNP) | VAF 19/263 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV55054634; called by muse, mutect2
- TACR3 | c.1289C>T p.T430M | Missense Mutation (SNP) | VAF 34/336 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.068); catalogued as rs200736098, COSV59200720; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TCERG1L | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 60/433 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.108); catalogued as rs1265256584; called by muse, mutect2, varscan2
- TDRD15 | c.3644A>G p.Y1215C | Missense Mutation (SNP) | VAF 34/324 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1325400825; called by muse, mutect2
- ULK3 | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 29/293 reads (10%) | catalogued as rs1049069646, COSV51513020; called by muse, mutect2, varscan2
- ULK4 | c.3401A>G p.K1134R | Missense Mutation (SNP) | VAF 36/277 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as COSV57226244; called by muse, mutect2, varscan2
- UNC13C | c.1637T>G p.L546R | Missense Mutation (SNP) | VAF 28/252 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs768743988, COSV52845905, COSV52871720; called by muse, mutect2, varscan2
- UNC13C | c.3561A>C p.E1187D | Missense Mutation (SNP) | VAF 28/349 reads (8%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.112); catalogued as rs938251241; called by muse, mutect2
- UNC45B | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 44/377 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs914857831, COSV52091938; called by muse, mutect2, varscan2
- VCAN | c.8093A>C p.K2698T | Missense Mutation (SNP) | VAF 38/414 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs770058352, COSV99426326; called by muse, mutect2
- WDR7 | c.3592C>T p.R1198* | Nonsense Mutation (SNP) | VAF 42/458 reads (9%) | catalogued as COSV54347064; called by muse, mutect2
- XKR6 | c.1771A>G p.R591G | Missense Mutation (SNP) | VAF 13/378 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV58655524; called by muse, mutect2
- ZNF106 | c.5197G>T p.V1733L | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.885); catalogued as rs377219331, COSV99782155; called by muse, mutect2
- ZNF14 | c.1388G>A p.R463Q | Missense Mutation (SNP) | VAF 36/420 reads (9%) | SIFT tolerated (0.97); PolyPhen benign (0.055); catalogued as rs202113659; called by muse, mutect2
- ZNF180 | c.1711C>T p.H571Y | Missense Mutation (SNP) | VAF 43/379 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55419909; called by muse, mutect2, varscan2
- ZNF521 | c.3437A>C p.K1146T | Missense Mutation (SNP) | VAF 32/382 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV100833107; called by muse, mutect2
- ZNF804B | c.122A>C p.K41T | Missense Mutation (SNP) | VAF 30/251 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV60824147; called by muse, mutect2, varscan2
- ZNF99 | c.401A>C p.N134T | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.61); catalogued as COSV68055080; called by muse, mutect2
- ACSL4 | c.1967C>G p.A656G (on ENST00000340800 / NM_022977.2; = p.A615G on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.097); called by muse, mutect2
- ACTRT1 | c.501del p.I168Sfs*45 | Frame Shift Del (DEL) | VAF 65/237 reads (27%) | called by mutect2, pindel, varscan2
- ANGPTL3 | c.1276C>A p.P426T | Missense Mutation (SNP) | VAF 27/299 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0.015); called by muse, mutect2
- AOPEP | c.1424C>T p.T475I | Missense Mutation (SNP) | VAF 13/406 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.376); called by muse, mutect2
- ASTN1 | c.2188T>G p.F730V | Missense Mutation (SNP) | VAF 51/343 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- BHLHE22 | c.811T>A p.Y271N | Missense Mutation (SNP) | VAF 17/614 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BRSK2 | c.1498C>T p.P500S | Missense Mutation (SNP) | VAF 37/338 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- C3orf38 | c.254C>G p.A85G | Missense Mutation (SNP) | VAF 35/325 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC63 | c.455A>C p.K152T | Missense Mutation (SNP) | VAF 33/259 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- CNTNAP5 | c.3283T>G p.F1095V | Missense Mutation (SNP) | VAF 28/302 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.089); called by muse, mutect2
- DCLK3 | c.1805A>G p.Y602C | Missense Mutation (SNP) | VAF 46/285 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DOCK9 | c.5134G>A p.V1712M (on ENST00000376460 / NM_001366676.2; = p.V1713M on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/260 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- ERBB3 | c.379_381del p.S128del | In Frame Del (DEL) | VAF 39/347 reads (11%) | called by mutect2, pindel, varscan2
- ERICH3 | c.2270A>G p.K757R | Missense Mutation (SNP) | VAF 33/376 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.059); called by muse, mutect2
- EZHIP | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 64/237 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- FAM47B | c.1809G>T p.M603I | Missense Mutation (SNP) | VAF 40/204 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- FLG | c.8450G>A p.S2817N | Missense Mutation (SNP) | VAF 46/788 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2
- FMN2 | c.1815T>G p.S605R | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- GMNC | c.578T>C p.L193P | Missense Mutation (SNP) | VAF 35/653 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GNA13 | c.996C>A p.N332K | Missense Mutation (SNP) | VAF 50/346 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by mutect2, varscan2
- GPR61 | c.773C>T p.S258F | Missense Mutation (SNP) | VAF 26/676 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GPRC5C | c.1423A>T p.N475Y (on ENST00000652232; = p.N430Y on NM_018653.4) | Missense Mutation (SNP) | VAF 48/380 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- H3Y1 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 54/405 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- IGHV3-16 | c.149A>C p.N50T | Missense Mutation (SNP) | VAF 14/439 reads (3%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2
- IGHV3OR16-12 | c.29T>G p.L10R | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- LPL | c.153G>T p.E51D | Missense Mutation (SNP) | VAF 36/405 reads (9%) | SIFT tolerated (0.79); PolyPhen benign (0.007); called by muse, mutect2
- LRRK2 | c.4064T>G p.M1355R | Missense Mutation (SNP) | VAF 36/321 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- MAD2L1 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 52/309 reads (17%) | called by muse, mutect2, varscan2
- MARCO | c.1308A>C p.E436D | Missense Mutation (SNP) | VAF 33/444 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- MLNR | c.313G>A p.V105M | Missense Mutation (SNP) | VAF 109/474 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- NAA15 | c.2174del p.D725Vfs*10 | Frame Shift Del (DEL) | VAF 39/218 reads (18%) | called by mutect2, pindel, varscan2
- NLRP6 | c.353A>G p.Y118C | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NUDT15 | c.426dup p.E143Rfs*5 | Frame Shift Ins (INS) | VAF 88/430 reads (20%) | called by mutect2, pindel, varscan2
- NUP210L | c.3145A>G p.I1049V | Missense Mutation (SNP) | VAF 35/284 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR10Z1 | c.188T>G p.L63R | Missense Mutation (SNP) | VAF 36/340 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR11L1 | c.442T>A p.S148T | Missense Mutation (SNP) | VAF 57/450 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2
- OR52E8 | c.771dup p.T258Yfs*15 | Frame Shift Ins (INS) | VAF 33/285 reads (12%) | called by mutect2, pindel, varscan2
- OSBPL7 | c.623T>C p.L208P | Missense Mutation (SNP) | VAF 32/337 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PDCL3 | c.560T>C p.M187T | Missense Mutation (SNP) | VAF 19/291 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.745); called by muse, mutect2
- PLEKHH1 | c.2156G>T p.S719I | Missense Mutation (SNP) | VAF 17/213 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.15); called by muse, mutect2
- PRR5-ARHGAP8 | c.1433T>G p.L478R (on ENST00000352766; = p.L399R on NM_181334.5) | Missense Mutation (SNP) | VAF 40/401 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- PURG | c.106C>A p.H36N | Missense Mutation (SNP) | VAF 43/499 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.017); called by muse, mutect2
- QKI | c.257T>G p.L86R | Missense Mutation (SNP) | VAF 25/262 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2
- R3HDM1 | c.1682G>A p.G561D | Missense Mutation (SNP) | VAF 37/415 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.022); called by muse, mutect2
- RBBP7 | c.542G>A p.G181D | Missense Mutation (SNP) | VAF 41/178 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RP1 | c.5108A>C p.K1703T | Missense Mutation (SNP) | VAF 34/417 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.012); called by muse, mutect2
- RPTN | c.102A>C p.K34N | Missense Mutation (SNP) | VAF 42/354 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SALL1 | c.1796A>G p.E599G | Missense Mutation (SNP) | VAF 40/350 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- SETD1A | c.3736G>A p.E1246K | Missense Mutation (SNP) | VAF 69/527 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SLC4A10 | c.810A>C p.E270D | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.006); called by muse, mutect2
- SMOC2 | c.1113A>C p.E371D (on ENST00000356284 / NM_001166412.2; = p.E382D on NM_022138.3) | Missense Mutation (SNP) | VAF 36/416 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TIMM21 | c.449G>A p.R150K | Missense Mutation (SNP) | VAF 29/231 reads (13%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- TLCD4 | c.776A>T p.N259I | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- TNFRSF11B | c.140G>A p.G47D | Missense Mutation (SNP) | VAF 23/369 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TSEN2 | c.678dup p.A227Cfs*11 | Frame Shift Ins (INS) | VAF 45/429 reads (10%) | called by mutect2, pindel, varscan2
- UHRF1BP1L | c.2238G>T p.Q746H | Missense Mutation (SNP) | VAF 32/346 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2
- USH2A | c.8889T>G p.F2963L | Missense Mutation (SNP) | VAF 10/316 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.033); called by muse, mutect2
- XRCC1 | c.1898C>G p.A633G | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- ZFP36L2 | c.478dup p.R160Pfs*314 | Frame Shift Ins (INS) | VAF 48/448 reads (11%) | called by mutect2, pindel, varscan2
- ZNF594 | c.1876_1880del p.C626Qfs*7 | Frame Shift Del (DEL) | VAF 27/219 reads (12%) | called by mutect2, pindel, varscan2
- ZNF648 | c.173G>T p.S58I | Missense Mutation (SNP) | VAF 39/501 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.272); called by muse, mutect2
- ZNF735 | c.781A>G p.R261G | Missense Mutation (SNP) | VAF 30/498 reads (6%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.793); called by muse, mutect2
- ADAMTS5 | c.120C>T p.A40= | Silent (SNP) | VAF 24/600 reads (4%) | called by muse, mutect2
- AGAP4 | c.1065C>T p.S355= | Silent (SNP) | VAF 63/567 reads (11%) | catalogued as rs1554896423; called by muse, mutect2, varscan2
- ANKRD55 | c.1524T>C p.T508= | Silent (SNP) | VAF 40/350 reads (11%) | called by muse, mutect2, varscan2
- ARFGEF2 | c.3033G>A p.T1011= | Silent (SNP) | VAF 45/353 reads (13%) | catalogued as rs750085797; called by muse, mutect2, varscan2
- ARHGAP21 | c.4398C>T p.G1466= | Silent (SNP) | VAF 20/370 reads (5%) | catalogued as rs1011776588; called by muse, mutect2
- ATP6V0A1 | c.1389C>T p.I463= | Silent (SNP) | VAF 41/389 reads (11%) | catalogued as rs1229575711; called by muse, mutect2, varscan2
- BBS2 | c.1557G>A p.L519= | Silent (SNP) | VAF 24/286 reads (8%) | catalogued as rs925476146; called by muse, mutect2
- BMP6 | c.531C>T p.G177= | Silent (SNP) | VAF 29/492 reads (6%) | called by muse, mutect2
- CBY2 | c.1095G>A p.A365= | Silent (SNP) | VAF 96/470 reads (20%) | catalogued as rs1479276727; called by muse, mutect2, varscan2
- CNPY3 | c.636C>T p.S212= | Silent (SNP) | VAF 29/333 reads (9%) | catalogued as rs371860465; called by muse, mutect2
- CNTN1 | c.1326G>A p.P442= | Silent (SNP) | VAF 34/380 reads (9%) | catalogued as rs1382743416, COSV61637213; ClinVar: likely benign; called by muse, mutect2
- CREB3L2 | c.954C>T p.Y318= | Silent (SNP) | VAF 35/415 reads (8%) | catalogued as rs957179549; called by muse, mutect2
- CYLC1 | c.462A>G p.R154= | Silent (SNP) | VAF 40/183 reads (22%) | called by muse, mutect2, varscan2
- CYP7B1 | c.960C>T p.D320= | Silent (SNP) | VAF 56/425 reads (13%) | catalogued as COSV59587784; called by muse, mutect2, varscan2
- DLG5 | c.4119C>T p.Y1373= | Silent (SNP) | VAF 26/692 reads (4%) | catalogued as rs746843270; called by muse, mutect2
- DLG5 | c.3096C>T p.S1032= | Silent (SNP) | VAF 129/626 reads (21%) | catalogued as rs199767734, COSV64950193; ClinVar: likely benign; called by muse, mutect2, varscan2
- DPYS | c.30C>T p.R10= | Silent (SNP) | VAF 34/442 reads (8%) | catalogued as COSV100680171; called by muse, mutect2
- ECPAS | c.2853C>T p.H951= | Silent (SNP) | VAF 37/355 reads (10%) | catalogued as rs779937190; called by muse, mutect2, varscan2
- ESPNL | c.828C>T p.H276= | Silent (SNP) | VAF 39/454 reads (9%) | catalogued as rs565056675; called by muse, mutect2
- FARSB | c.489T>C p.D163= | Silent (SNP) | VAF 31/338 reads (9%) | called by muse, mutect2
- FGD3 | c.2175G>A p.P725= | Silent (SNP) | VAF 29/275 reads (11%) | catalogued as rs374534280; called by muse, mutect2, varscan2
- GALNT5 | c.1266G>A p.Q422= | Silent (SNP) | VAF 30/387 reads (8%) | called by muse, mutect2
- HOXA3 | c.291C>T p.A97= | Silent (SNP) | VAF 66/617 reads (11%) | catalogued as rs1205317798; called by muse, mutect2, varscan2
- HOXD11 | c.558C>T p.P186= | Silent (SNP) | VAF 45/459 reads (10%) | catalogued as rs1325326191; called by muse, mutect2, varscan2
- IGHV3OR16-13 | c.132T>C p.S44= | Silent (SNP) | VAF 46/356 reads (13%) | called by muse, mutect2, varscan2
- IL4I1 | c.1308C>T p.D436= | Silent (SNP) | VAF 52/433 reads (12%) | called by muse, mutect2, varscan2
- KCNV2 | c.363G>A p.T121= | Silent (SNP) | VAF 60/487 reads (12%) | catalogued as rs773398432, COSV66056772; called by muse, mutect2, varscan2
- KLK6 | c.75C>T p.G25= | Silent (SNP) | VAF 32/362 reads (9%) | catalogued as rs1401187950, COSV59565425; called by muse, mutect2
- KRT72 | c.30C>T p.R10= | Silent (SNP) | VAF 38/342 reads (11%) | catalogued as rs1222422528; called by muse, mutect2, varscan2
- LARP6 | c.1068G>A p.A356= | Silent (SNP) | VAF 45/449 reads (10%) | catalogued as rs780604042; called by muse, mutect2, varscan2
- LHX2 | c.606C>T p.G202= | Silent (SNP) | VAF 73/516 reads (14%) | catalogued as rs1236729567; called by muse, mutect2, varscan2
- LOXHD1 | c.441C>T p.S147= | Silent (SNP) | VAF 47/385 reads (12%) | called by muse, mutect2, varscan2
- LRRIQ3 | c.688T>C p.L230= | Silent (SNP) | VAF 15/193 reads (8%) | catalogued as COSV63043542, COSV63049378; called by muse, mutect2
- LY6H | c.141G>A p.P47= | Silent (SNP) | VAF 51/394 reads (13%) | catalogued as rs576428006, COSV61371276; called by muse, mutect2, varscan2
- MAP3K13 | c.1629G>T p.G543= | Silent (SNP) | VAF 36/470 reads (8%) | called by muse, mutect2
- MAP4 | c.1371C>T p.N457= | Silent (SNP) | VAF 50/364 reads (14%) | catalogued as rs377266613; called by muse, mutect2, varscan2
- MSANTD1 | c.111G>A p.A37= | Silent (SNP) | VAF 25/511 reads (5%) | catalogued as rs377153773; called by muse, mutect2
- NCOR1 | c.1605A>G p.E535= | Silent (SNP) | VAF 12/142 reads (8%) | called by muse, mutect2
- NKX2-8 | c.543C>T p.C181= | Silent (SNP) | VAF 74/551 reads (13%) | catalogued as rs1422962562; called by muse, mutect2, varscan2
- NPFFR2 | c.117C>T p.R39= | Silent (SNP) | VAF 46/412 reads (11%) | catalogued as COSV58148681; called by muse, mutect2, varscan2
- NUB1 | c.1722G>A p.T574= (on ENST00000568733 / NM_001243351.1; = p.T560= on NM_016118.4) | Silent (SNP) | VAF 27/345 reads (8%) | catalogued as rs779226162; called by muse, mutect2
- OLIG2 | c.123G>A p.S41= | Silent (SNP) | VAF 60/445 reads (13%) | catalogued as rs1446616283, COSV60973375; called by muse, mutect2, varscan2
- OR10K2 | c.171C>T p.I57= | Silent (SNP) | VAF 43/391 reads (11%) | catalogued as COSV59220312, COSV59220374; called by muse, mutect2, varscan2
- OR14C36 | c.741A>G p.S247= | Silent (SNP) | VAF 32/351 reads (9%) | catalogued as rs534338585; called by muse, mutect2
- OR5D13 | c.259T>C p.L87= | Silent (SNP) | VAF 32/315 reads (10%) | catalogued as COSV62334051; called by muse, mutect2, varscan2
- PCDH18 | c.750T>G p.S250= | Silent (SNP) | VAF 61/308 reads (20%) | catalogued as COSV61270064; called by muse, mutect2, varscan2
- PCDHA9 | c.1521C>T p.Y507= | Silent (SNP) | VAF 63/695 reads (9%) | catalogued as rs540017466, COSV65324130; called by muse, mutect2
- PCDHGB1 | c.1875G>A p.A625= | Silent (SNP) | VAF 56/400 reads (14%) | catalogued as rs747746357, COSV53915448; called by muse, mutect2, varscan2
- PDCD1LG2 | c.606T>C p.L202= | Silent (SNP) | VAF 43/337 reads (13%) | called by muse, mutect2, varscan2
- PDZRN4 | c.6C>T p.G2= | Silent (SNP) | VAF 30/258 reads (12%) | called by muse, mutect2, varscan2
- PENK | c.609C>T p.A203= | Silent (SNP) | VAF 50/416 reads (12%) | called by muse, mutect2, varscan2
- PHACTR3 | c.708T>G p.T236= | Silent (SNP) | VAF 35/312 reads (11%) | called by mutect2, varscan2
- PHLDB2 | c.168T>C p.S56= | Silent (SNP) | VAF 22/376 reads (6%) | called by muse, mutect2
- PKDREJ | c.54C>T p.V18= | Silent (SNP) | VAF 43/385 reads (11%) | catalogued as rs1271026117; called by muse, mutect2, varscan2
- PTGDR | c.681G>A p.A227= | Silent (SNP) | VAF 55/491 reads (11%) | catalogued as COSV60093457, COSV60093749; called by muse, mutect2, varscan2
- PTPRN2 | c.1407G>A p.A469= | Silent (SNP) | VAF 38/550 reads (7%) | catalogued as rs765722971, COSV67023396; called by muse, mutect2
- RHBDF2 | c.567G>A p.P189= | Silent (SNP) | VAF 36/314 reads (11%) | catalogued as rs773527172; called by muse, varscan2
- SCN10A | c.2679C>T p.F893= | Silent (SNP) | VAF 28/228 reads (12%) | called by muse, mutect2, varscan2
- SESN1 | c.333G>A p.P111= (on ENST00000356644 / NM_001199933.1; = p.P170= on NM_014454.3) | Silent (SNP) | VAF 30/296 reads (10%) | catalogued as rs749467712; called by muse, mutect2, varscan2
- SLC5A4 | c.144G>C p.L48= | Silent (SNP) | VAF 16/326 reads (5%) | called by muse, mutect2
- TDRD15 | c.2697T>G p.T899= | Silent (SNP) | VAF 19/243 reads (8%) | called by muse, mutect2
- TEX13C | c.2406C>A p.P802= | Silent (SNP) | VAF 22/266 reads (8%) | called by muse, mutect2
- TGM6 | c.732C>T p.G244= | Silent (SNP) | VAF 72/440 reads (16%) | catalogued as rs200686759, COSV52478133; called by muse, mutect2, varscan2
- TMEM97 | c.183G>A p.E61= | Silent (SNP) | VAF 31/328 reads (9%) | catalogued as COSV56879441; called by muse, mutect2, varscan2
- TNFAIP2 | c.78G>A p.A26= | Silent (SNP) | VAF 22/290 reads (8%) | catalogued as rs1180039346; called by muse, mutect2
- TNR | c.2826C>T p.S942= | Silent (SNP) | VAF 57/370 reads (15%) | catalogued as rs145986923, COSV54869266; called by muse, mutect2, varscan2
- TTN | c.43926C>T p.T14642= (on ENST00000591111; = p.T7218= on NM_003319.4) | Silent (SNP) | VAF 30/357 reads (8%) | catalogued as rs768147224, COSV100617463, COSV60291972; ClinVar: likely benign; called by muse, mutect2
- TTN | c.3178A>C p.R1060= (on ENST00000591111; = p.R1014= on NM_003319.4) | Silent (SNP) | VAF 43/286 reads (15%) | called by muse, mutect2, varscan2
- YIPF7 | c.255T>G p.G85= | Silent (SNP) | VAF 28/356 reads (8%) | called by muse, mutect2
- ZBED9 | c.1989T>C p.S663= | Silent (SNP) | VAF 34/318 reads (11%) | called by muse, mutect2, varscan2
- ZNF569 | c.397A>C p.R133= | Silent (SNP) | VAF 17/305 reads (6%) | catalogued as COSV57594078; called by muse, mutect2
- ARHGEF4 | chr2:130916502 C>T | 5'Flank (SNP) | VAF 53/579 reads (9%) | catalogued as rs1291191543, COSV58131975; called by muse, mutect2
- ASIC2 | c.556-179549C>T | Intron (SNP) | VAF 79/609 reads (13%) | catalogued as COSV99859136; called by muse, mutect2, varscan2
- CLN5 | c.*239C>T | 3'UTR (SNP) | VAF 34/338 reads (10%) | called by muse, mutect2, varscan2
- DNM1 | c.1335+1779G>A | Intron (SNP) | VAF 21/224 reads (9%) | catalogued as rs764731504, COSV57856802; called by muse, mutect2, varscan2
- IGKV1D-8 | c.-1C>A | 5'UTR (SNP) | VAF 54/506 reads (11%) | called by muse, mutect2
- KCNJ10 | c.*799A>C | 3'UTR (SNP) | VAF 47/280 reads (17%) | called by muse, mutect2, varscan2
- LINC01615 | n.589T>G | RNA (SNP) | VAF 15/182 reads (8%) | called by muse, mutect2
- MTDHP2 | n.560A>C | RNA (SNP) | VAF 42/307 reads (14%) | called by muse, mutect2, varscan2
- SIM1 | c.*649A>T | 3'UTR (SNP) | VAF 28/298 reads (9%) | called by muse, mutect2
- WWOX | c.1056+258522C>A | Intron (SNP) | VAF 20/285 reads (7%) | called by muse, mutect2
- ZZZ3 | c.-307G>A | 5'UTR (SNP) | VAF 30/269 reads (11%) | catalogued as rs916647118; called by muse, mutect2, varscan2
